Somatic mutation profile of tumor specimen MMRF_1656_4_BM_CD138pos (aliquot MMRF_1656_4_BM_CD138pos_T1_KHS5U_L11617) from MMRF case MMRF_1656, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.0 years (25,923 days).
Specimen MMRF_1656_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 583602a3-4bb8-4055-8fc0-d22ecf3357d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1656_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1656_1_PB_Whole_C3_KBS5U_L04408; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f969d59a-3320-4be2-b8a2-b2c4c70eb765

The open-access MAF lists 155 somatic variants for this specimen: 66 protein-altering or splice-affecting, 27 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, 3'UTR 28, Silent 27, Intron 20, 5'Flank 5, 5'UTR 5, Nonsense Mutation 3, RNA 2, Frame Shift Del 2, 3'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 58/91 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AMOT | c.1295C>T p.S432F (on ENST00000371959 / NM_001113490.1; = p.S23F on NM_133265.3) | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs768761923; called by muse, mutect2, varscan2
- C8B | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 34/35 reads (97%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs147387692; called by muse, mutect2, varscan2
- CACNA2D3 | c.2527G>A p.G843S | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.299); catalogued as rs1406059160; called by muse, mutect2
- DEFA4 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 39/308 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs754867893; called by muse, mutect2, varscan2
- FGFR3 | c.820C>T p.H274Y | Missense Mutation (SNP) | VAF 102/202 reads (50%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as rs900590386, COSV53422348; called by muse, mutect2, varscan2
- FSIP2 | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); catalogued as COSV58077913, COSV58096657; called by muse, mutect2
- GLB1L3 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV101111108; called by muse, mutect2
- HABP2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as COSV63636488; called by muse, mutect2, varscan2
- HOXB1 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 91/184 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs755351120, COSV53316586, COSV99495463; called by muse, mutect2, varscan2
- IGHJ1 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 48/49 reads (98%) | catalogued as rs371876779; called by muse, mutect2, varscan2
- IGHJ4 | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 62/62 reads (100%) | PolyPhen possibly damaging (0.902); catalogued as rs532078280; called by muse, mutect2, varscan2
- IGHV2-70 | c.136T>A p.F46I | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs368473747; called by muse, varscan2
- IGHV2-70 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs530408879; called by muse, varscan2
- IGLV3-1 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 80/85 reads (94%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs373323725; called by muse, varscan2
- IGLV3-25 | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 171/241 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs377194630; called by muse, mutect2, varscan2
- KIAA0319 | c.2900T>C p.I967T | Missense Mutation (SNP) | VAF 120/272 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs758963733; called by muse, mutect2, varscan2
- KRT86 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs1397640624; called by muse, mutect2, varscan2
- MICALL2 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1304638450; called by muse, mutect2, varscan2
- MYEF2 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 131/447 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51047982, COSV51055213; called by muse, mutect2, varscan2
- NEB | c.3385G>T p.D1129Y | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99424260; called by muse, mutect2
- NME8 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 68/129 reads (53%) | catalogued as rs142023810; called by muse, mutect2, varscan2
- SALL1 | c.2903G>T p.G968V | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.813); catalogued as COSV51764000; called by muse, mutect2
- SKA3 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs777253375; called by muse, mutect2, varscan2
- TTC25 | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs554993453; called by muse, mutect2, varscan2
- VDAC2 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as rs200130063; called by muse, mutect2
- ZNF25 | c.1193A>G p.Y398C | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs758284706; called by muse, mutect2, varscan2
- ATP11B | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATP1A4 | c.2302G>C p.V768L | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by muse, mutect2
- BCR | c.212A>G p.D71G | Missense Mutation (SNP) | VAF 117/269 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BDP1 | c.6211A>T p.S2071C | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2
- CCDC82 | c.1598_1599del p.F533Cfs*10 | Frame Shift Del (DEL) | VAF 104/360 reads (29%) | called by mutect2, pindel, varscan2
- CEP104 | c.326A>C p.K109T | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); called by muse, mutect2
- CNTNAP4 | c.979A>T p.R327* | Nonsense Mutation (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- CRAT | c.527T>A p.I176N | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUL7 | c.3226C>T p.Q1076* | Nonsense Mutation (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- EML6 | c.3340A>G p.T1114A | Missense Mutation (SNP) | VAF 120/262 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FOSL2 | c.404A>T p.K135M | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FYTTD1 | c.16A>G p.T6A | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGSF9B | c.1635G>A p.M545I | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KLC4 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2
- KPNA6 | c.263T>C p.M88T | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MDM4 | c.166T>G p.L56V | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MLPH | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.097); called by muse, mutect2
- MYLPF | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 89/264 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- MYO19 | c.2511A>T p.E837D (on ENST00000614623 / NM_001163735.1; = p.E637D on NM_025109.5) | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MYO5C | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- NCOA2 | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- OR4K14 | c.884T>C p.M295T | Missense Mutation (SNP) | VAF 124/348 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- OR7A5 | c.215G>A p.C72Y | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.369); called by muse, mutect2
- PCF11 | c.3607T>G p.F1203V | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PCNX3 | c.1943T>A p.V648E | Missense Mutation (SNP) | VAF 123/431 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PGM3 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 15/372 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2
- PLEKHG1 | c.1966G>T p.D656Y | Missense Mutation (SNP) | VAF 90/174 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- POM121L2 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPFIBP1 | c.1174T>G p.F392V (on ENST00000318304 / NM_177444.3; = p.F375V on NM_003622.4) | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PTCHD4 | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 78/172 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- RHOC | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- RNF146 | c.292del p.S98Vfs*42 (on ENST00000368314 / NM_001242850.2; = p.S97Vfs*42 on NM_030963.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 77/207 reads (37%) | called by mutect2, pindel, varscan2
- TENT5C | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 78/120 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM221 | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 97/269 reads (36%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- TMPRSS11D | c.443A>C p.N148T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TSHZ3 | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- VARS1 | c.3349G>A p.A1117T | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2
- YY1 | c.1016A>C p.K339T | Missense Mutation (SNP) | VAF 163/310 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF292 | c.2477dup p.H827Afs*4 | Frame Shift Ins (INS) | VAF 134/294 reads (46%) | called by mutect2, varscan2
- ACE2 | c.759T>A p.P253= | Silent (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- ASXL3 | c.4530C>T p.S1510= | Silent (SNP) | VAF 87/282 reads (31%) | catalogued as rs566372551; called by muse, mutect2, varscan2
- ATP9B | c.2802C>T p.F934= | Silent (SNP) | VAF 42/149 reads (28%) | catalogued as rs764301018, COSV100303708; called by muse, mutect2, varscan2
- C1orf158 | c.144C>A p.S48= | Silent (SNP) | VAF 10/226 reads (4%) | catalogued as COSV99847378; called by muse, mutect2
- CELSR3 | c.5988C>T p.C1996= | Silent (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- CSRNP3 | c.483T>A p.I161= | Silent (SNP) | VAF 26/640 reads (4%) | called by muse, mutect2
- EBF3 | c.1242C>T p.S414= (on ENST00000355311 / NM_001375392.1; = p.S405= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as rs771823461, COSV62471852, COSV62477068; called by muse, mutect2, varscan2
- ERAP2 | c.1443C>T p.Y481= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs773321134; called by muse, mutect2, varscan2
- GLI4 | c.801C>T p.Y267= | Silent (SNP) | VAF 58/161 reads (36%) | catalogued as rs1413038969; called by muse, mutect2, varscan2
- IGLV3-27 | c.66G>A p.E22= | Silent (SNP) | VAF 93/212 reads (44%) | catalogued as rs573159010; called by muse, mutect2, varscan2
- METTL22 | c.717C>G p.L239= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV50837991; called by muse, mutect2, varscan2
- MZF1 | c.1849A>C p.R617= | Silent (SNP) | VAF 52/189 reads (28%) | called by muse, mutect2, varscan2
- NCKAP5 | c.3100C>T p.L1034= | Silent (SNP) | VAF 59/113 reads (52%) | called by muse, mutect2, varscan2
- NPAS1 | c.576A>T p.S192= | Silent (SNP) | VAF 37/128 reads (29%) | called by muse, mutect2, varscan2
- PCDH9 | c.2499C>T p.T833= | Silent (SNP) | VAF 146/269 reads (54%) | catalogued as rs1253905807; called by muse, mutect2, varscan2
- PSMA6 | c.54C>T p.P18= | Silent (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- SF3B1 | c.3856A>C p.R1286= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as COSV59228177; called by muse, mutect2
- SHROOM4 | c.3900C>T p.G1300= | Silent (SNP) | VAF 99/106 reads (93%) | catalogued as rs1049181461; called by muse, mutect2, varscan2
- SIRT2 | c.42A>G p.A14= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2
- SLC4A1 | c.345C>G p.T115= | Silent (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- SLC6A17 | c.1416C>A p.G472= | Silent (SNP) | VAF 111/115 reads (97%) | called by muse, mutect2, varscan2
- TLR3 | c.2085T>C p.S695= | Silent (SNP) | VAF 22/428 reads (5%) | called by muse, mutect2
- TYK2 | c.2115T>C p.H705= | Silent (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- UTRN | c.4281G>A p.V1427= | Silent (SNP) | VAF 9/211 reads (4%) | called by muse, mutect2
- ZFHX3 | c.2187G>A p.E729= | Silent (SNP) | VAF 15/320 reads (5%) | catalogued as rs768531141; called by muse, mutect2
- ZNF432 | c.984G>A p.G328= | Silent (SNP) | VAF 26/324 reads (8%) | catalogued as COSV55416318; called by muse, mutect2
- ZNF451 | c.642T>C p.C214= | Silent (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- ADO | c.*1479A>C | 3'UTR (SNP) | VAF 4/85 reads (5%) | called by muse, mutect2
- AGFG1 | c.*1627G>A | 3'UTR (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- BSG | chr19:571637 C>T | 5'Flank (SNP) | VAF 9/252 reads (4%) | called by muse, mutect2
- C14orf132 | c.*6209dup | 3'UTR (INS) | VAF 27/61 reads (44%) | catalogued as rs1236551791; called by mutect2, pindel, varscan2
- C19orf12 | chr19:29701508 ins T | 3'Flank (INS) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- CACNA1B | c.5223-1596A>G | Intron (SNP) | VAF 39/121 reads (32%) | called by muse, mutect2, varscan2
- CALM2 | chr2:47176572 G>T | 5'Flank (SNP) | VAF 37/75 reads (49%) | catalogued as rs899633621; called by muse, mutect2, varscan2
- CARMIL1 | c.-71A>G | 5'UTR (SNP) | VAF 143/281 reads (51%) | called by muse, mutect2, varscan2
- CCAR2 | c.585-172_585-169del | Intron (DEL) | VAF 5/21 reads (24%) | called by mutect2, pindel, varscan2
- CD72 | c.352+132G>T | Intron (SNP) | VAF 22/738 reads (3%) | called by muse, mutect2
- CDK7 | c.*205T>C | 3'UTR (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- COA1 | c.-38-53G>A | Intron (SNP) | VAF 39/88 reads (44%) | called by muse, mutect2, varscan2
- COLQ | c.107-8943G>A | Intron (SNP) | VAF 60/116 reads (52%) | called by muse, mutect2, varscan2
- CREB3L2 | c.103-25076G>A | Intron (SNP) | VAF 100/201 reads (50%) | called by muse, mutect2, varscan2
- CTNNA2 | c.*332T>G | 3'UTR (SNP) | VAF 32/59 reads (54%) | called by muse, mutect2, varscan2
- CYGB | chr17:76538211 C>T | 5'Flank (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- DHDDS | c.542+723G>A | Intron (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- FANCD2P2 | n.666T>G | RNA (SNP) | VAF 12/23 reads (52%) | called by muse, varscan2
- IL1RAPL1 | c.*557G>A | 3'UTR (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- ILRUN | c.158+26C>G | Intron (SNP) | VAF 4/61 reads (7%) | called by muse, mutect2
- IMMP2L | c.*394A>G | 3'UTR (SNP) | VAF 68/127 reads (54%) | called by muse, mutect2, varscan2
- KLHL21 | c.*1579G>T | 3'UTR (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- KRTAP4-7 | c.*446T>C | 3'UTR (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- LYNX1 | c.*407G>A | 3'UTR (SNP) | VAF 100/215 reads (47%) | catalogued as rs13267427; called by muse, mutect2, varscan2
- MAN2B2 | c.2815-789G>A | Intron (SNP) | VAF 78/230 reads (34%) | called by muse, mutect2, varscan2
- MAP9 | c.1822-2249C>G | Intron (SNP) | VAF 180/368 reads (49%) | called by muse, mutect2, varscan2
- MED10 | c.*469G>A | 3'UTR (SNP) | VAF 39/122 reads (32%) | called by muse, mutect2, varscan2
- MNT | c.*2G>A | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- MON1B | c.*3832G>A | 3'UTR (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- NDUFS7 | c.544+393C>T | Intron (SNP) | VAF 18/212 reads (8%) | catalogued as rs549979856; called by muse, mutect2
- NPR3 | chr5:32710153 C>A | 5'Flank (SNP) | VAF 143/450 reads (32%) | called by muse, mutect2, varscan2
- OPA1 | chr3:193593146 G>T | 5'Flank (SNP) | VAF 171/350 reads (49%) | called by muse, mutect2, varscan2
- PAPPA2 | c.*977T>C | 3'UTR (SNP) | VAF 49/138 reads (36%) | called by muse, mutect2
- PEX5 | chr12:7210778 G>A | 3'Flank (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- PHF24 | c.*3087A>C | 3'UTR (SNP) | VAF 107/175 reads (61%) | called by muse, mutect2, varscan2
- PKHD1 | c.10156+23163T>A | Intron (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- PNMA8A | c.-39T>C | 5'UTR (SNP) | VAF 25/295 reads (8%) | called by muse, mutect2
- PNPLA5 | c.*99G>C | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- POU3F3 | c.*651C>T | 3'UTR (SNP) | VAF 36/92 reads (39%) | called by muse, mutect2, varscan2
- PPM1A | c.*2673C>T | 3'UTR (SNP) | VAF 52/99 reads (53%) | called by muse, mutect2, varscan2
- PRRC1 | c.1128+1153G>C | Intron (SNP) | VAF 5/121 reads (4%) | called by muse, mutect2
- PSEN1 | c.869-156A>C | Intron (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- PSMD13 | c.569-85dup | Intron (INS) | VAF 20/32 reads (63%) | catalogued as rs374061872; called by mutect2, varscan2
- RHOU | c.*142G>A | 3'UTR (SNP) | VAF 80/141 reads (57%) | called by muse, mutect2, varscan2
- RNF213 | c.*869T>A | 3'UTR (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- RUNDC3A | c.-52C>A | 5'UTR (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- SBK1 | c.*299C>T | 3'UTR (SNP) | VAF 14/140 reads (10%) | catalogued as rs1473131759; called by muse, mutect2
- SCUBE2 | c.*469G>A | 3'UTR (SNP) | VAF 15/202 reads (7%) | called by muse, mutect2
- SERPINB4 | c.*253C>T | 3'UTR (SNP) | VAF 26/670 reads (4%) | catalogued as rs1465440924; called by muse, mutect2
- SH3BGRL2 | c.*1754del | 3'UTR (DEL) | VAF 20/43 reads (47%) | catalogued as rs982815110; called by mutect2, varscan2
- SH3D19 | c.-206C>T | 5'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- SLC12A2 | c.*2194A>T | 3'UTR (SNP) | VAF 46/158 reads (29%) | called by muse, mutect2, varscan2
- SLC9A5 | c.734-111G>A | Intron (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- SNRNP200 | c.*251G>A | 3'UTR (SNP) | VAF 45/101 reads (45%) | called by muse, mutect2, varscan2
- SNX29P1 | n.708G>C | RNA (SNP) | VAF 84/394 reads (21%) | called by muse, mutect2, varscan2
- STARD4 | c.*3609T>A | 3'UTR (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2
- TRAPPC2 | c.-19-62T>C | Intron (SNP) | VAF 16/75 reads (21%) | called by muse, mutect2, varscan2
- TRIM27 | c.920-36C>T | Intron (SNP) | VAF 64/124 reads (52%) | catalogued as rs781360991; called by muse, mutect2, varscan2
- TRIM55 | c.1524+1289G>A | Intron (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- VILL | c.-86-120C>T | Intron (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- ZNF30 | c.-40A>C | 5'UTR (SNP) | VAF 247/396 reads (62%) | catalogued as COSV100340291; called by muse, mutect2
- ZNF529 | c.*118T>G | 3'UTR (SNP) | VAF 9/19 reads (47%) | called by muse, varscan2
